Somatic mutation profile of tumor specimen ALCH-B1R8-TTP1-A (aliquot ALCH-B1R8-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1R8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,383 days).
Specimen ALCH-B1R8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc4fe1c4-d723-4f8b-b3fc-579126293af5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1R8-NB1-A (Blood Derived Normal), aliquot ALCH-B1R8-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/137961ae-0e4d-469c-826d-485c41177e55

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 4, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK5RAP1 | c.1190A>C p.Q397P (on ENST00000357886 / NM_001365728.1; = p.Q383P on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs756464565; called by muse, mutect2, varscan2
- MUC5AC | c.16481C>T p.T5494M | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.868); catalogued as rs754121316, COSV100611661; called by muse, mutect2, varscan2
- MYO9B | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 87/281 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs775612949; called by muse, mutect2, varscan2
- SETD2 | c.4622A>G p.N1541S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV57439960; called by muse, mutect2, varscan2
- SMPD2 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs1239678240, COSV57806173; called by muse, mutect2, varscan2
- TAF9B | c.275dup p.L92Ffs*17 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs1206415946; called by mutect2, pindel, varscan2
- TBC1D22A | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs988342620; called by muse, mutect2, varscan2
- TNFRSF8 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141205943; called by muse, mutect2, varscan2
- ANKRD35 | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAZ2A | c.4954C>G p.R1652G | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CIT | c.5681G>A p.R1894K | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CPAMD8 | c.1289T>C p.I430T (on ENST00000651564; = p.I383T on NM_015692.5) | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FKBP15 | c.325-2A>C p.X109_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- GPAT2 | c.2122C>T p.L708F | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IDH3B | c.750dup p.D251Rfs*15 | Frame Shift Ins (INS) | VAF 50/289 reads (17%) | called by mutect2, pindel, varscan2
- KIRREL1 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- LAMA2 | c.6268+6A>T | Splice Region (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3583C>G p.Q1195E | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- RAB4B | c.74_76del p.L25del | In Frame Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTLL5 | c.798T>G p.H266Q | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP1 | c.1802C>G p.T601S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.1); called by muse, varscan2
- WDR49 | c.262C>G p.L88V (on ENST00000308378 / NM_001366158.1; = p.L429V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ZNF226 | c.1332A>T p.E444D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- ZNF774 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALK | c.3348C>A p.I1116= | Silent (SNP) | VAF 231/765 reads (30%) | catalogued as rs374587233; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCL9 | c.2844A>G p.P948= | Silent (SNP) | VAF 14/263 reads (5%) | called by muse, mutect2
- HSPA12A | c.1455C>T p.A485= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs782363366, COSV65022948; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PITX3 | c.45C>T p.A15= | Silent (SNP) | VAF 42/254 reads (17%) | called by muse, mutect2, varscan2
- AGXT2 | chr5:35049125 del GGGAGTGATCATATGAGCTGGCT | 5'Flank (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- ALK | c.3173-50T>C | Intron (SNP) | VAF 87/288 reads (30%) | called by muse, mutect2, varscan2
- EPB41L1 | c.-15+769A>G | Intron (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2, varscan2
- GAA | c.2190-47C>T | Intron (SNP) | VAF 45/125 reads (36%) | catalogued as rs1310198454; called by muse, mutect2, varscan2
- TGFB3 | c.646+11C>T | Intron (SNP) | VAF 65/299 reads (22%) | called by muse, mutect2, varscan2
